Gene-level copy-number profile of tumor specimen TCGA-V4-A9E9-01A from TCGA case TCGA-V4-A9E9, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.3 years (18,387 days).
Specimen TCGA-V4-A9E9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.3aaabdca-edf4-4b00-af94-7565a6db4172.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V4-A9E9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/299ccc5c-7758-4d01-9a93-de6c8b5e7f29

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,980; copy number 2: 51,239; copy number 3: 3,151; copy number 4: 188; copy number 5: 1,262.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V4-A9E9-01A-11D-A39V-01): tumor purity 1, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,262 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–22,654,455, 371 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:7,640,711–62,275,678, 891 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,599. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
